Gene-level copy-number profile of specimen HCM-CSHL-0608-C17-85A from HCMI case HCM-CSHL-0608-C17, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Atypical carcinoid tumor; Tissue or organ of origin: Small intestine, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 39.8 years (14,534 days).
Specimen HCM-CSHL-0608-C17-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 88479cdf-1c5e-4abb-8e23-206c130e9e6c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0608-C17-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/1a4257dc-2281-4532-823f-47b2691079e7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 58; copy number 1: 430; copy number 2: 55,245; copy number 3: 165; copy number 4: 2,501.

Homozygous deletions (total copy number 0; autosomes only): 58 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:46,123,031–47,269,033, 38 genes: AC024475.3, AC024475.2, LINC02710, AC116021.1, LINC02489, CREB3L1, DGKZ, MIR4688, MDK, CHRM4, AMBRA1, AC024293.1, MIR3160-1, MIR3160-2, AC127035.1, HARBI1, ATG13, ARHGAP1, ZNF408, F2, CKAP5, MIR5582, AC115088.1, SNORD67, LRP4-AS1, LRP4, C11orf49, AC103792.1, AC090589.2, ARFGAP2, AC090589.3, PACSIN3, MIR6745, AC090589.1, DDB2, AC018410.1, ACP2, NR1H3.
- chr11:115,128,218–115,128,373, 1 gene: AP003179.1.
- chr11:121,979,571–122,872,643, 19 genes: AP001924.1, RNU6-256P, MIR100HG, MIR125B1, BLID, MIRLET7A2, MIR100, AP000755.1, AP000755.2, RNU4ATAC10P, RNU4ATAC5P, RNU6-592P, GLULP3, AP002469.1, UBASH3B, AP002762.3, AP002762.1, AP002762.2, CRTAM.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 430. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
